Surgical pathology report (de-identified scan), TCGA case TCGA-4X-A9FC, project TCGA-THYM (Thymoma), tissue source site Yale University, specimen TCGA-4X-A9FC-01A (Primary Tumor).

[page 1 of 2]
Print Date/time:

Printed by:

Patient:

MRN:

DOB:

SEX:

Pathology Report: THYMUS- FROZEN/AP WINDOWCase

Provider:

Location of Care:

THYMUS- FROZEN/AP WINDOWCase #:

1) THYMUS, EXCISION:

- THYMOMA, TYPE AB (SEE NOTE)
- RESECTION MARGINS ARE NEGATIVE
- THREE LYMPH NODES NEGATIVE FOR MALIGNANCY (0/3)

2) SOFT TISSUE, "AP WINDOW", EXCISION:

- BENIGN THYMIC AND FIBROADIPOSE TISSUE
- NO NEOPLASM IDENTIFIED

NOTE: CD1a, CD3, and CK19 immunostains were performed to better highlight the component of this tumor. This is a heterogenous neoplasm with areas showing predominantly spindled epithelial cells (type A areas). However, the majority of the tumor is lymphocyte rich, and CD1a staining confirms that the vast majority of the lymphocytes are immature. These areas are most consistent with a type B2 thymoma. Taken together, this is a type AB thymoma.

GROSS DESCRIPTION

1) Received fresh for frozen section, labeled with the patient's name and "thymus" is 104 gm, 21 x 7 x 3 cm tan-red soft tissue with a well circumscribed hard nodule measuring 5.5 x 4.5 x 3 cm. Serial sectioning reveals homogenous tan cut surface in the nodule without evidence of hemorrhage or softening. There is a suture indicating pericardial surface which is inked blue and the opposite surface is inked yellow. One representative section is submitted in one block. Frozen section remains are submitted in cassette #1 labeled FSC. Additional representative sections of the nodule is submitted in cassettes #2-6. Tumor to neighboring lobulated fatty tissue is submitted in cassette #7 and flanking fatty tissue is submitted in cassette #8. The tumor sections represent approximately 35% of the entire nodule.

2) Received fresh, labeled with the patient's name and "AP window tissue" is a 1.5 x 1 x 0.4 cm fibroadipose tissue which is inked black, bisected and entirely submitted in one cassette.

FROZEN SECTION DIAGNOSIS

1) "Thymoma: No margin involvement at the suture" (1 block)

Internal Review

Stage:

ICD-O-3
Thymoma, type AB,
malignant 8582/3
Site: Thymus C37.9
JW 6/24/14

[page 2 of 2]
Print Date/time:

Printed by

Patient:

MRN:

DOB:

SEX:

This tumor is grossly well circumscribed. However, microscopically there is invasion of the tumor into and focally through the capsule. Foci of possible vascular involvement are also identified. These features correspond to a Masaoka stage II lesion.

Signed by Pathologist:

Signed before import by
Filed automatically on

Source: NCI Genomic Data Commons file ad979224-bcaa-45dd-83b0-4885b285b60e (TCGA-4X-A9FC.31BA5AEF-EE4D-4BBE-8B5D-32FB28F4AE3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).